Somatic mutation profile of tumor specimen TCGA-G4-6310-01A (aliquot TCGA-G4-6310-01A-11D-1719-10) from TCGA case TCGA-G4-6310, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 69.1 years (25,243 days).
Specimen TCGA-G4-6310-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e4780f4-c530-4538-ab6c-b3b64e31b887.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6310-10A (Blood Derived Normal), aliquot TCGA-G4-6310-10A-01D-1720-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/576d1dab-9f1c-427f-ae0b-c6800decc04c

The open-access MAF lists 114 somatic variants for this specimen: 81 protein-altering or splice-affecting, 32 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 32, Nonsense Mutation 7, Splice Site 2, Frame Shift Del 2, In Frame Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC34A1 | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 12/88 reads (14%) | catalogued as rs200893951, COSV60995579; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 35/71 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.465dup p.T156Yfs*6 | Frame Shift Ins (INS) | VAF 55/210 reads (26%) | catalogued as rs1180724229; called by mutect2, varscan2
- ABCC1 | c.2795C>T p.A932V | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.097); catalogued as rs375097324; called by muse, mutect2, varscan2
- AC126283.2 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 48/189 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.34); catalogued as rs754851037, COSV67097939; called by muse, mutect2, varscan2
- ADGRL2 | c.4226G>T p.S1409I (on ENST00000370717 / NM_001366005.1; = p.S1353I on NM_012302.4) | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54655089; called by muse, mutect2, varscan2
- ADIPOR2 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 106/260 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV63945544; called by muse, mutect2, varscan2
- AKAP9 | c.989T>A p.I330N | Missense Mutation (SNP) | VAF 116/459 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100662253; called by muse, mutect2, varscan2
- APC | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 112/188 reads (60%) | catalogued as COSV57325414, COSV57354660, COSV57393116, COSV99964740; called by muse, mutect2, varscan2
- APP | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.925); catalogued as COSV60994653; called by muse, mutect2, varscan2
- ATP9A | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 12/255 reads (5%) | catalogued as rs1161132652, COSV100124742; called by muse, mutect2
- BPIFA3 | c.755C>T p.S252F | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.077); catalogued as COSV64925628; called by muse, mutect2
- C3orf22 | c.297C>G p.N99K | Missense Mutation (SNP) | VAF 135/356 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV59072486; called by muse, mutect2, varscan2
- CBL | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV50630643, COSV50658859; called by muse, mutect2, varscan2
- CDH12 | c.1324G>A p.A442T | Missense Mutation (SNP) | VAF 40/223 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.348); catalogued as rs551198422, COSV66460340; called by muse, mutect2, varscan2
- CDH18 | c.1664G>A p.R555K | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV56900038; called by muse, mutect2, varscan2
- CFAP58 | c.2290G>A p.V764I | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs773079523, COSV63832796; called by muse, mutect2, varscan2
- CLUH | c.3320A>G p.D1107G (on ENST00000435359; = p.D1146G on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101425711; called by muse, mutect2
- CNTN5 | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199794950, COSV54285547, COSV54309805; called by muse, mutect2, varscan2
- COL27A1 | c.3811G>A p.V1271I | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs558210767, COSV61922131; called by muse, mutect2, varscan2
- CRYZ | c.975G>T p.M325I | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV61717060; called by muse, mutect2, varscan2
- CSMD2 | c.613A>G p.T205A | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV53884818; called by muse, mutect2, varscan2
- DNAJB11 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54001957; called by muse, mutect2, varscan2
- DNMT3A | c.2158C>T p.R720C | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1197133406, COSV53039088, COSV53040923; called by muse, mutect2, varscan2
- DPY19L3 | c.1897G>T p.D633Y | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60474877, COSV60478799; called by muse, mutect2, varscan2
- DST | c.20770C>T p.L6924F (on ENST00000361203 / NM_001374722.1; = p.L4621F on NM_015548.5) | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1294070269, COSV55000478; called by muse, mutect2, varscan2
- DYNC1H1 | c.11795C>T p.A3932V | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs752716582, COSV64134761; called by muse, mutect2, varscan2
- ERC1 | c.2446C>T p.R816* (on ENST00000360905 / NM_178040.4; = p.R788* on NM_178039.4) | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as rs1391616148, COSV61692049; called by muse, mutect2, varscan2
- FBXO22 | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as rs1377869208, COSV51191972; called by muse, mutect2, varscan2
- GCG | c.481A>C p.N161H | Missense Mutation (SNP) | VAF 60/207 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV64960909; called by muse, mutect2, varscan2
- GFRA1 | c.1271G>A p.G424D | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as rs747338729, COSV100815648; called by muse, mutect2, varscan2
- GLI3 | c.2056C>T p.R686W | Missense Mutation (SNP) | VAF 83/373 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs138199980; called by muse, mutect2, varscan2
- GPATCH2L | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.794); catalogued as COSV55047016; called by muse, mutect2, varscan2
- GRIA4 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.372); catalogued as rs763888983, COSV56884103, COSV99233797; called by muse, mutect2, varscan2
- HAVCR2 | c.102del p.Y35Ifs*41 | Frame Shift Del (DEL) | VAF 31/154 reads (20%) | catalogued as COSV57154352; called by mutect2, pindel, varscan2
- HHIPL2 | c.1230C>G p.H410Q | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV58563436; called by muse, mutect2, varscan2
- HOXD12 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66832348; called by muse, mutect2, varscan2
- ISL1 | c.413G>T p.R138M | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV57932610; called by muse, mutect2, varscan2
- JAK3 | c.2090G>A p.R697Q | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs200849846, COSV71685719, COSV71685731; called by muse, mutect2
- KCND2 | c.1532G>A p.R511H | Missense Mutation (SNP) | VAF 115/233 reads (49%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.375); catalogued as rs35460901; called by muse, mutect2, varscan2
- KDM7A | c.178G>T p.D60Y | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50090203; called by muse, varscan2
- KIF5B | c.1425T>A p.N475K | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.028); catalogued as COSV56651140; called by muse, mutect2, varscan2
- MAGEB4 | c.508A>T p.N170Y | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV66775283; called by muse, mutect2, varscan2
- MFHAS1 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1450551591, COSV52282481; called by muse, mutect2
- MFSD13A | c.828+1G>A p.X276_splice | Splice Site (SNP) | VAF 28/140 reads (20%) | catalogued as COSV53266506; called by muse, mutect2, varscan2
- MTDH | c.1277C>G p.S426* | Nonsense Mutation (SNP) | VAF 21/38 reads (55%) | catalogued as COSV60342832; called by muse, mutect2, varscan2
- MYPOP | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.18); catalogued as COSV56193006; called by muse, mutect2, varscan2
- MYT1L | c.1770C>A p.C590* | Nonsense Mutation (SNP) | VAF 55/105 reads (52%) | catalogued as COSV67710411, COSV67714700; called by muse, mutect2, varscan2
- NPAP1 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs144589407; called by muse, mutect2, varscan2
- NTM | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 71/230 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1434180187, COSV66173976, COSV66180621; called by muse, mutect2, varscan2
- OAS2 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60801358; called by muse, mutect2, varscan2
- PCDHB8 | c.2170G>A p.G724S | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.082); catalogued as rs782123508, COSV50755318; called by muse, mutect2, varscan2
- PCNT | c.1232A>G p.H411R | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100854929, COSV64028322; called by muse, mutect2, varscan2
- PCNT | c.7162C>T p.R2388C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs201562329, COSV100855360; ClinVar: likely benign; called by muse, mutect2, varscan2
- PDHA2 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs267600306, COSV54776945; called by muse, mutect2, varscan2
- PHKB | c.1054C>G p.P352A | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV54515627; called by muse, mutect2, varscan2
- POLR3GL | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100996774; called by muse, mutect2, varscan2
- PPP1R12B | c.1941+1G>A p.X647_splice | Splice Site (SNP) | VAF 28/112 reads (25%) | catalogued as rs1233389370, COSV51782145; called by muse, varscan2
- PXDN | c.1735T>G p.L579V | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV53227924; called by muse, mutect2, varscan2
- RNF43 | c.1802C>A p.S601Y | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.188); catalogued as COSV101348375, COSV68458156; called by muse, mutect2, varscan2
- SERPINI1 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as COSV55508315; called by muse, mutect2, varscan2
- SLC38A8 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.213); catalogued as rs200651717, COSV55310427; called by muse, mutect2, varscan2
- SLCO2A1 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs192851611; called by muse, mutect2, varscan2
- SLFN13 | c.2053A>G p.K685E | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV99539916; called by muse, mutect2
- SLX4 | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs773558127, COSV53561308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMAD3 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as rs1429991069, COSV59287781; called by muse, mutect2, varscan2
- SRPX2 | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.967); catalogued as rs1449724154, COSV100884016; called by muse, mutect2, varscan2
- SYNE1 | c.16741A>G p.S5581G (on ENST00000367255 / NM_182961.4; = p.S5510G on NM_033071.3) | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99560269; called by muse, mutect2, varscan2
- TMEM82 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252236088, COSV65387051; called by muse, mutect2, varscan2
- TNIK | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 89/181 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs772057234, COSV52675169; called by muse, mutect2, varscan2
- TOPBP1 | c.4552C>T p.R1518* | Nonsense Mutation (SNP) | VAF 15/298 reads (5%) | catalogued as COSV53434981; called by muse, mutect2
- TRIM37 | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.257); catalogued as COSV51881791; called by muse, mutect2, varscan2
- TRPM4 | c.2778G>A p.M926I | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53260588; called by muse, mutect2, varscan2
- VPS13D | c.2527G>A p.V843M | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs529005238, COSV50623926; called by muse, mutect2, varscan2
- WHRN | c.2032G>A p.G678S | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs200037348; called by muse, mutect2, varscan2
- ZC3H7B | c.2486T>A p.I829N | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60960746; called by muse, mutect2, varscan2
- ZFHX4 | c.7927G>A p.G2643R | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs375729228, COSV50531518; called by muse, mutect2, varscan2
- ZNF112 | c.250C>G p.Q84E (on ENST00000337401 / NM_001083335.2; = p.Q78E on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100495662; called by muse, mutect2, varscan2
- ZSWIM3 | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 34/229 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV54845430; called by muse, mutect2, varscan2
- CYFIP1 | c.363del p.K121Nfs*2 | Frame Shift Del (DEL) | VAF 11/102 reads (11%) | called by mutect2, pindel, varscan2
- NIPBL | c.3515_3523del p.M1172_K1174del | In Frame Del (DEL) | VAF 130/735 reads (18%) | called by mutect2, pindel, varscan2
- ADAM20 | c.1002C>T p.V334= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as rs749297139, COSV56454203; called by muse, mutect2, varscan2
- ADAMTS2 | c.273G>A p.P91= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as rs768036305, COSV51072480, COSV51093578; called by muse, mutect2, varscan2
- AP2S1 | c.307C>T p.L103= | Silent (SNP) | VAF 307/525 reads (58%) | catalogued as COSV54383585; called by muse, mutect2, varscan2
- C20orf141 | c.420G>T p.G140= | Silent (SNP) | VAF 9/202 reads (4%) | catalogued as rs1254600522, COSV63027842; called by muse, mutect2
- CNGA3 | c.207G>T p.G69= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as rs778557545, COSV55622655; called by muse, mutect2, varscan2
- CYP51A1 | c.897G>A p.G299= | Silent (SNP) | VAF 33/260 reads (13%) | catalogued as COSV50150998; called by muse, mutect2, varscan2
- DCAF12L1 | c.1245T>C p.D415= | Silent (SNP) | VAF 96/140 reads (69%) | catalogued as COSV64421248; called by muse, mutect2, varscan2
- DNAH17 | c.3915C>T p.N1305= | Silent (SNP) | VAF 53/607 reads (9%) | catalogued as rs1264741430, COSV67750359; called by muse, mutect2
- DOK6 | c.267G>A p.S89= | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as rs766192217, COSV66926858; called by muse, mutect2, varscan2
- DUSP29 | c.249C>T p.H83= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as COSV100633287; called by muse, mutect2, varscan2
- E2F7 | c.1971C>T p.G657= | Silent (SNP) | VAF 22/217 reads (10%) | catalogued as COSV59737668; called by muse, mutect2, varscan2
- EBLN2 | c.189C>T p.D63= | Silent (SNP) | VAF 33/134 reads (25%) | catalogued as rs373449895; called by muse, mutect2, varscan2
- FAT2 | c.2649C>T p.R883= | Silent (SNP) | VAF 20/243 reads (8%) | catalogued as rs373152684; called by muse, mutect2
- GBP7 | c.993C>A p.A331= | Silent (SNP) | VAF 92/213 reads (43%) | catalogued as COSV54008324; called by muse, mutect2, varscan2
- LAT | c.324G>A p.A108= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as rs530922450, COSV57953789; called by muse, mutect2, varscan2
- LINGO1 | c.324C>T p.S108= | Silent (SNP) | VAF 45/188 reads (24%) | catalogued as rs777483987, COSV62436836; called by muse, mutect2, varscan2
- LIPA | c.1008G>A p.P336= | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as rs376895620, COSV100290256; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRFN5 | c.57C>A p.I19= | Silent (SNP) | VAF 90/257 reads (35%) | catalogued as COSV53244968; called by muse, mutect2, varscan2
- MMP28 | c.276G>A p.G92= | Silent (SNP) | VAF 22/139 reads (16%) | called by muse, mutect2, varscan2
- NT5E | c.711C>T p.D237= | Silent (SNP) | VAF 34/248 reads (14%) | catalogued as rs778273365, COSV57627404; called by muse, mutect2, varscan2
- OR2A12 | c.609G>A p.A203= | Silent (SNP) | VAF 76/260 reads (29%) | catalogued as rs539744343, COSV68821029; called by muse, mutect2, varscan2
- PCDHB2 | c.1617C>A p.G539= | Silent (SNP) | VAF 25/42 reads (60%) | catalogued as COSV50564705; called by muse, mutect2, varscan2
- SEC14L5 | c.528G>A p.S176= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs145531258, COSV99228644; called by muse, mutect2, varscan2
- SLC32A1 | c.1245C>T p.R415= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as COSV54145812; called by muse, mutect2
- SLC6A15 | c.2034C>T p.H678= | Silent (SNP) | VAF 84/199 reads (42%) | catalogued as rs140619291, COSV57020560; called by muse, mutect2, varscan2
- TMEM151A | c.768C>T p.R256= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs751316586, COSV100516901; called by muse, mutect2
- TMEM8B | c.120G>A p.P40= | Silent (SNP) | VAF 53/120 reads (44%) | catalogued as rs548793454, COSV65075769; called by muse, mutect2, varscan2
- TNXB | c.12849C>T p.N4283= (on ENST00000647633; = p.N4036= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 136/377 reads (36%) | catalogued as rs766412096, COSV64474533; called by muse, mutect2, varscan2
- TTN | c.65337G>A p.P21779= (on ENST00000591111; = p.P14355= on NM_003319.4) | Silent (SNP) | VAF 87/280 reads (31%) | catalogued as rs72646887, COSV59910139; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- VAV1 | c.1542C>T p.N514= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs199798227; called by muse, mutect2, varscan2
- ZNF366 | c.651C>T p.A217= | Silent (SNP) | VAF 37/177 reads (21%) | catalogued as rs376626591; called by muse, mutect2, varscan2
- ZNF517 | c.411G>A p.P137= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as rs764649958, COSV63464545; called by muse, mutect2, varscan2
- AC005863.1 | n.298C>G | RNA (SNP) | VAF 31/131 reads (24%) | called by muse, mutect2, varscan2
